Gene-level copy-number profile of tumor specimen ALCH-B35S-TTP1-A from ALCHEMIST case ALCH-B35S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,208 days).
Specimen ALCH-B35S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6f9e9759-34e2-4f5b-8ac7-bad69b75f1e4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B35S-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/9c98b505-b7fe-463a-82c8-f571fbc66cdd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 325; copy number 1: 10,999; copy number 2: 44,789; copy number 3: 2,613; copy number 4: 108; copy number 5: 16; copy number 6: 3; copy number 7: 44; copy number 9: 2; copy number 12: 2; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 106 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,532,166–46,570,255, 3 genes (within-gene range 0–2): TMEM275, MKNK1-AS1, KNCN.
- chr2:25,042,076–25,342,590, 7 genes: EFR3B, RN7SL856P, SUCLA2P3, POMC, LINC01381, DNMT3A, MIR1301.
- chr2:72,916,260–72,936,071, 2 genes: EMX1, AC012366.1.
- chr2:90,121,786–90,173,414, 4 genes: IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11.
- chr2:91,578,478–91,580,863, 2 genes: AC233266.1, AC233266.2.
- chr3:53,224,712–53,256,052, 1 gene: TKT.
- chr5:139,644,460–139,775,472, 8 genes: AC113361.1, CXXC5, CXXC5-AS1, AC008667.1, RNU6-236P, PSD2-AS1, AC008667.3, AC008667.4.
- chr8:30,678,066–30,767,006, 3 genes: GSR, UBXN8, HIKESHIP3.
- chr9:6,639,139–6,707,780, 7 genes (within-gene range 0–2): RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–1): CRB2.
- chr9:123,402,525–123,493,156, 3 genes (within-gene range 0–1): MIR601, MIR7150, AL445489.1.
- chr9:124,853,417–124,877,733, 3 genes: WDR38, RPL35, ARPC5L.
- chr9:124,887,410–124,887,549, 1 gene (within-gene range 0–2): RNU4-82P.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr11:72,576,141–72,674,591, 5 genes: PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1.
- chr11:72,685,075–72,693,808, 1 gene (within-gene range 0–1): ARAP1-AS1.
- chr11:72,754,729–72,793,681, 2 genes (within-gene range 0–2): STARD10, Y_RNA.
- chr11:72,793,624–72,843,674, 2 genes (within-gene range 0–2): AP002381.2, ATG16L2.
- chr14:91,418,266–91,421,176, 2 genes: AL133153.2, AL133153.1.
- chr14:92,923,150–93,116,320, 3 genes (within-gene range 0–1): CHGA, ITPK1, ITPK1-AS1.
- chr15:25,184,306–25,239,919, 31 genes (within-gene range 0–2): SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38.
- chr15:77,568,970–77,608,888, 1 gene: AC046168.2.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–1): RNU6-1191P.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:2,720,801–2,723,947, 1 gene: AC005696.4.
- chr20:3,732,685–3,806,121, 5 genes: HSPA12B, C20orf27, SPEF1, CENPB, CDC25B.
- chr20:32,443,059–32,585,074, 4 genes (within-gene range 0–2): NOL4L, AL034550.1, AL034550.3, AL034550.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 68 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:1,683,269–1,697,755, 3 genes, copy number 5: FAM99B, LINC02708, KRTAP5-6.
- chr16:991,151–1,000,926, 1 gene, copy number 6: AC009041.1.
- chr16:1,221,651–1,242,554, 4 genes, copy number 9–12 (within-gene range 4–12): TPSG1, AC120498.10, TPSB2, TPSAB1.
- chr16:1,260,952–1,263,845, 1 gene, copy number 18: PRSS29P.
- chr18:33,578,219–35,934,142, 35 genes, copy number 5–7: ASXL3, NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929.
- chr18:36,777,647–37,236,242, 4 genes, copy number 7 (within-gene range 4–7): TPGS2, KIAA1328, AC016493.1, AC015961.1.
- chr18:37,657,135–40,144,504, 18 genes, copy number 7: MIR4318, RPL12P40, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45.
- chr20:62,302,093–62,308,862, 2 genes, copy number 6 (within-gene range 3–6): ADRM1, AL354836.1.

Autosomal genes at a single copy (total copy number 1): 8,705. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
